Somatic mutation profile of tumor specimen 0DPZTI from CCDI case PBCAET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.3 years (3,036 days).
Specimen 0DPZTI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fa48241-5ae6-46c4-a06f-f591f1b4d177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZU7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de3e47cd-cc81-4b9c-aa97-d2c872097b69

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2D | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.792); catalogued as rs1321805855; called by muse, mutect2, varscan2
- MNDA | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs780190760; called by muse, mutect2, varscan2
- TRPV1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs765271282, COSV51515068; called by muse, mutect2, varscan2
- RPS25 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RPS25 | c.-49G>C | 5'UTR (SNP) | VAF 154/367 reads (42%) | called by muse, mutect2, varscan2
- TUBB4B | c.-25C>A | 5'UTR (SNP) | VAF 81/230 reads (35%) | called by muse, mutect2, varscan2
